Somatic mutation profile of tumor specimen TCGA-A4-7915-01A (aliquot TCGA-A4-7915-01A-11D-2201-08) from TCGA case TCGA-A4-7915, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 35.1 years (12,832 days).
Specimen TCGA-A4-7915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72662394-5a9f-4eab-8e39-e0107aa8213e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7915-10A (Blood Derived Normal), aliquot TCGA-A4-7915-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccb8cff7-08a3-448a-8c45-531639693675

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Splice Site 2, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.943); catalogued as COSV56647726; called by muse, mutect2, varscan2
- ANO5 | c.2080C>A p.P694T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV61090786; called by muse, mutect2, varscan2
- GRM2 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587872; called by muse, mutect2, varscan2
- ITGAL | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV63323879; called by muse, mutect2, varscan2
- KDELR3 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 74/259 reads (29%) | catalogued as rs1423841252, COSV53249934; called by muse, mutect2, varscan2
- LAMB1 | c.4201C>T p.P1401S | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs1562974794, COSV55969962, COSV55970901; called by muse, mutect2
- LPIN2 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.981); catalogued as COSV55245010; called by muse, mutect2, varscan2
- MRPL54 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs200308520, COSV57463794; called by muse, mutect2, varscan2
- PAPPA2 | c.5215G>A p.D1739N | Missense Mutation (SNP) | VAF 80/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62813270; called by muse, mutect2, varscan2
- PRDM16 | c.3095A>G p.H1032R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV54582178, COSV54611120; called by muse, mutect2, varscan2
- PTPRZ1 | c.4481G>T p.S1494I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.205); catalogued as COSV66446538; called by muse, mutect2, varscan2
- RCOR2 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56851693; called by muse, mutect2, varscan2
- SCARA5 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs752998049, COSV61572090, COSV61574497; called by muse, mutect2, varscan2
- SLC35D3 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV59378453; called by muse, mutect2, varscan2
- SLC36A4 | c.180-1G>T p.X60_splice | Splice Site (SNP) | VAF 47/130 reads (36%) | catalogued as COSV58397891; called by muse, mutect2, varscan2
- TP53RK | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.721); catalogued as COSV64509218; called by muse, mutect2, varscan2
- USF3 | c.3670G>T p.A1224S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV57077930; called by muse, mutect2, varscan2
- ARHGAP35 | c.943del p.Q315Rfs*32 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- CADPS | c.2944_2946del p.V982del | In Frame Del (DEL) | VAF 46/171 reads (27%) | called by pindel, varscan2
- DNAJA2 | c.138+1del p.X46_splice | Splice Site (DEL) | VAF 40/153 reads (26%) | called by mutect2, pindel, varscan2
- PAPSS2 | c.1092C>T p.D364= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs771350788, COSV63265291; called by muse, mutect2, varscan2
- RBM4B | c.66C>T p.F22= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as COSV59498331; called by muse, mutect2, varscan2
- SHD | c.978C>T p.A326= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs111268424, COSV56669085; called by muse, mutect2, varscan2
- TAS1R1 | c.2373C>T p.A791= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV59840962; called by muse, mutect2, varscan2
